Somatic mutation profile of tumor specimen 0DXVLB from CCDI case PBCRFD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical meningioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.4 years (4,906 days).
Specimen 0DXVLB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86b8ac2c-33f2-4577-af09-d631498530c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXMLI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47e80878-a31d-4bcf-8fe7-462e718faaa3

The open-access MAF lists 374 somatic variants for this specimen: 178 protein-altering or splice-affecting, 100 silent, 96 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 100, Intron 53, 3'UTR 15, 5'UTR 12, 5'Flank 8, Frame Shift Del 5, Splice Region 5, RNA 4, 3'Flank 4, In Frame Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LATS2 | c.1431_1436dup p.P479_A480dup | In Frame Ins (INS) | VAF 246/1119 reads (22%) | hotspot (GDC flag); catalogued as rs550642106, COSV66878166, COSV66880240; called by mutect2, varscan2
- AACS | c.999C>T p.V333= | Splice Region (SNP) | VAF 157/565 reads (28%) | catalogued as rs756256590; called by muse, mutect2, varscan2
- ABCC5 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 228/1252 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs369277426; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.754G>C p.V252L | Missense Mutation (SNP) | VAF 137/714 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.055); catalogued as rs202206383; called by muse, mutect2, varscan2
- ADGRF3 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 294/1274 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.054); catalogued as rs202027387; called by muse, varscan2
- ADGRG6 | c.2660T>C p.V887A | Missense Mutation (SNP) | VAF 158/704 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs938403456; called by muse, mutect2, varscan2
- AGXT2 | c.1000T>C p.W334R | Missense Mutation (SNP) | VAF 281/1153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202180854; called by muse, mutect2, varscan2
- ALPK2 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 127/625 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs991756104, COSV64495653; called by muse, mutect2, varscan2
- ANKRD36B | c.3668A>C p.N1223T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs538343994; called by mutect2, varscan2
- AQP12B | c.455T>C p.L152P (on ENST00000621682; = p.L164P on NM_001102467.2) | Missense Mutation (SNP) | VAF 180/821 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.757); catalogued as rs777721855; called by muse, varscan2
- ARAP1 | c.1271G>A p.R424Q (on ENST00000393609 / NM_001040118.2; = p.R179Q on NM_015242.4) | Missense Mutation (SNP) | VAF 198/920 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs143371904; called by muse, mutect2, varscan2
- ARHGAP39 | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 122/529 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as rs758906504; called by muse, mutect2, varscan2
- ARL3 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs763678922; called by muse, mutect2, varscan2
- ASCC3 | c.5320G>A p.D1774N | Missense Mutation (SNP) | VAF 185/777 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1031903529, COSV64972965; called by muse, mutect2, varscan2
- ASPM | c.9553G>C p.A3185P | Missense Mutation (SNP) | VAF 194/782 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375985254; called by muse, mutect2, varscan2
- ASTE1 | c.985G>C p.V329L | Missense Mutation (SNP) | VAF 210/1078 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs775998053; called by muse, mutect2, varscan2
- ATF6 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 160/776 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs141227581, COSV63407689; called by muse, mutect2, varscan2
- ATG4D | c.1306C>G p.Q436E | Missense Mutation (SNP) | VAF 168/902 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV57264298; called by muse, mutect2, varscan2
- ATP11A | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 150/832 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs751075008, COSV52106208; called by muse, mutect2, varscan2
- ATP5PB | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 186/883 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as rs201778705, COSV71953333; called by muse, mutect2, varscan2
- ATRAID | c.169G>C p.A57P (on ENST00000611786; = p.A2P on NM_001170795.3) | Missense Mutation (SNP) | VAF 170/890 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as rs200120344; called by muse, mutect2, varscan2
- BAHCC1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 173/967 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs782784821; called by muse, mutect2, varscan2
- BCO1 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 178/840 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as rs896361256; called by muse, mutect2, varscan2
- BEST1 | c.779del p.P260Qfs*29 | Frame Shift Del (DEL) | VAF 202/1022 reads (20%) | catalogued as rs778645644; called by mutect2, pindel, varscan2
- BMP8A | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 116/580 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.068); catalogued as rs776950479; called by muse, mutect2, varscan2
- C4orf17 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 289/1216 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs763635728; called by muse, mutect2, varscan2
- C8orf34 | c.132C>A p.H44Q | Missense Mutation (SNP) | VAF 205/882 reads (23%) | SIFT tolerated, low confidence (0.35); catalogued as rs528666239; called by muse, mutect2, varscan2
- CACNA1B | c.5455G>A p.A1819T | Missense Mutation (SNP) | VAF 269/1086 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs200122209; called by muse, mutect2, varscan2
- CACNA2D2 | c.553A>G p.S185G | Missense Mutation (SNP) | VAF 216/1129 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs368540577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAND2 | c.1985G>A p.R662Q (on ENST00000456430 / NM_001162499.2; = p.R569Q on NM_012298.3) | Missense Mutation (SNP) | VAF 227/1262 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs1319245795; called by muse, mutect2, varscan2
- CASP8AP2 | c.4698_4719delinsACAT p.T1567_G1573delinsH | In Frame Del (DEL) | VAF 137/882 reads (16%) | catalogued as rs751783405; called by pindel, varscan2*
- CBLB | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 241/1104 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs760589517, COSV51436298; called by muse, mutect2, varscan2
- CDYL2 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 226/1098 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778603352, COSV73653964; called by muse, mutect2, varscan2
- CEP164 | c.2356C>T p.R786W | Missense Mutation (SNP) | VAF 162/747 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); catalogued as rs139225491; called by muse, mutect2, varscan2
- CEP43 | c.102G>A p.K34= | Splice Region (SNP) | VAF 104/567 reads (18%) | catalogued as rs1028879519; called by muse, mutect2, varscan2
- CFHR5 | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 142/625 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs915090892; called by muse, mutect2, varscan2
- CLIP1 | c.1859T>C p.I620T (on ENST00000620786 / NM_001247997.1; = p.I609T on NM_002956.2) | Missense Mutation (SNP) | VAF 225/1083 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs765209495; called by muse, mutect2, varscan2
- CNPPD1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 118/460 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs764464830; called by muse, mutect2, varscan2
- COL4A4 | c.4546G>A p.V1516I | Missense Mutation (SNP) | VAF 136/669 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs199517662; called by muse, mutect2, varscan2
- CR2 | c.1597A>T p.I533F | Missense Mutation (SNP) | VAF 106/591 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs762951469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRAT | c.935del p.G312Afs*92 | Frame Shift Del (DEL) | VAF 112/628 reads (18%) | catalogued as rs777281947; called by mutect2, varscan2
- CYP2F1 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 225/1088 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs142026539; called by muse, mutect2, varscan2
- DGAT2 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 146/605 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs555522864; called by muse, mutect2, varscan2
- DGKI | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 177/788 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.637); catalogued as rs1356117537; called by muse, mutect2, varscan2
- DGLUCY | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 205/1106 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs201623410; called by muse, mutect2, varscan2
- DNAH1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 226/1271 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368210345; called by muse, mutect2, varscan2
- DNAH9 | c.615C>G p.V205= | Splice Region (SNP) | VAF 159/764 reads (21%) | catalogued as rs369344808; called by muse, mutect2, varscan2
- DSTYK | c.2764_2767del p.N922Efs*3 | Frame Shift Del (DEL) | VAF 165/779 reads (21%) | catalogued as rs746299902; called by mutect2, pindel, varscan2
- EPPK1 | c.14038G>C p.G4680R | Missense Mutation (SNP) | VAF 208/1738 reads (12%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.98); catalogued as rs1339103457; called by muse, varscan2
- EXTL3 | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 172/755 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754765415; called by muse, mutect2, varscan2
- FAM214B | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 245/1289 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs757132238; called by muse, mutect2, varscan2
- FAM83B | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 201/845 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs370292018; called by muse, mutect2, varscan2
- FAN1 | c.1389A>C p.Q463H | Missense Mutation (SNP) | VAF 108/433 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs780829453; called by muse, mutect2, varscan2
- FBLN5 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 208/1086 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.785); catalogued as rs140452924; called by muse, mutect2, varscan2
- FEZF2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 108/568 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs773733664; called by mutect2, varscan2
- FKBP15 | c.3386C>T p.T1129I | Missense Mutation (SNP) | VAF 193/873 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs753439653; called by muse, mutect2, varscan2
- FMOD | c.145A>C p.T49P | Missense Mutation (SNP) | VAF 158/690 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs965718572; called by muse, mutect2, varscan2
- FNDC1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 195/875 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1464178551; called by muse, mutect2, varscan2
- FNIP1 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 144/635 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs150752291; called by muse, mutect2, varscan2
- FRYL | c.5852G>A p.R1951Q | Missense Mutation (SNP) | VAF 264/1075 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as rs764039685, COSV51946067; called by muse, mutect2, varscan2
- GABRB3 | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 193/819 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs763319754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT8 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 149/646 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs376084995; called by muse, mutect2, varscan2
- GAMT | c.212T>C p.M71T | Missense Mutation (SNP) | VAF 195/994 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as rs1359526308; called by muse, mutect2, varscan2
- GAS7 | c.416C>T p.A139V (on ENST00000432992 / NM_201433.2; = p.A79V on NM_201432.2) | Missense Mutation (SNP) | VAF 169/871 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs765026371, COSV60444678; called by muse, mutect2, varscan2
- GCLC | c.954A>T p.P318= (on ENST00000643939; = p.P316= on NM_001498.4) | Splice Region (SNP) | VAF 70/290 reads (24%) | catalogued as rs201680153; called by muse, mutect2, varscan2
- GDPGP1 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 168/841 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs755241008; called by muse, mutect2, varscan2
- GOLGA6L1 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 87/1204 reads (7%) | SIFT tolerated, low confidence (0.06); catalogued as rs1380478462; called by muse, varscan2
- HPS3 | c.969C>G p.T323= | Splice Region (SNP) | VAF 236/1223 reads (19%) | catalogued as rs199556788; called by muse, mutect2, varscan2
- HSPA4 | c.2069A>G p.Q690R | Missense Mutation (SNP) | VAF 146/576 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs368330661; called by muse, varscan2
- HSPG2 | c.6706G>A p.E2236K | Missense Mutation (SNP) | VAF 136/747 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762159760, COSV65970087; called by muse, mutect2, varscan2
- INPP5B | c.1958A>G p.E653G (on ENST00000373023; = p.E573G on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/659 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs891129877; called by muse, mutect2, varscan2
- INTU | c.92T>A p.F31Y | Missense Mutation (SNP) | VAF 224/949 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148080788; called by muse, varscan2
- IQCH | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 105/395 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs777209863, COSV60053144; called by muse, mutect2, varscan2
- IRS4 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 219/814 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs1015888477; called by muse, mutect2, varscan2
- ITGA10 | c.3349C>T p.R1117W | Missense Mutation (SNP) | VAF 233/1084 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs140404631; called by muse, mutect2, varscan2
- ITGA9 | c.2275C>G p.L759V | Missense Mutation (SNP) | VAF 154/846 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.086); catalogued as rs148785471; called by muse, mutect2, varscan2
- KDM6B | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 245/1267 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as rs200835362; called by muse, mutect2, varscan2
- KIF19 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 190/857 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs574552018; called by muse, mutect2, varscan2
- LMAN1L | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 154/620 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs776294214; called by muse, mutect2, varscan2
- LMF1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 300/1399 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs762740737; called by muse, mutect2, varscan2
- LOXHD1 | c.6055G>A p.E2019K (on ENST00000642948; = p.E1957K on NM_144612.7) | Missense Mutation (SNP) | VAF 148/627 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs373848470, CM153973, CM165129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LOXHD1 | c.1730T>G p.L577R | Missense Mutation (SNP) | VAF 283/1282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs727503147, CM165128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRIG1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 125/602 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.179); catalogued as rs1449152767; called by muse, mutect2, varscan2
- MAGI2 | c.4250G>T p.R1417L | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1181205613; called by muse, mutect2
- MARVELD2 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 185/795 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767827863; called by muse, mutect2, varscan2
- MICAL3 | c.3841C>T p.R1281C | Missense Mutation (SNP) | VAF 149/544 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs747674587, COSV71588224, COSV71588421; called by muse, varscan2
- MSH3 | c.169_195del p.A57_A65del | In Frame Del (DEL) | VAF 329/914 reads (36%) | catalogued as rs762256716; called by pindel, varscan2*
- MUC5B | c.4034A>G p.N1345S | Missense Mutation (SNP) | VAF 238/1008 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as rs758090330; called by muse, mutect2, varscan2
- MUC6 | c.1760G>A p.C587Y | Missense Mutation (SNP) | VAF 125/598 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.285); catalogued as rs372497281; called by muse, mutect2, varscan2
- MXRA5 | c.4523C>G p.T1508S | Missense Mutation (SNP) | VAF 193/932 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs768643932; called by muse, mutect2, varscan2
- MXRA5 | c.3473G>A p.R1158H | Missense Mutation (SNP) | VAF 158/874 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs112514198, COSV54237183; called by muse, mutect2, varscan2
- MXRA5 | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 183/715 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs753064443; called by muse, mutect2, varscan2
- MYLK2 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 137/746 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs551492045; called by muse, mutect2, varscan2
- MYO18B | c.6503C>T p.T2168I | Missense Mutation (SNP) | VAF 233/869 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs368257345; called by muse, mutect2, varscan2
- NAA11 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 218/954 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs530619715, COSV99727286; called by muse, mutect2, varscan2
- NAA16 | c.1202T>C p.I401T | Missense Mutation (SNP) | VAF 121/656 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs984841131, COSV65064967; called by muse, mutect2, varscan2
- NCBP2L | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 244/864 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs760879365; called by muse, mutect2, varscan2
- NLRP5 | c.3487T>C p.Y1163H | Missense Mutation (SNP) | VAF 110/463 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs372525725; called by muse, varscan2
- NOC2L | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 114/501 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as rs200633429; called by muse, mutect2, varscan2
- NPC1 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 189/882 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs150053420; ClinVar: uncertain significance; called by muse, varscan2
- NSMCE3 | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 115/455 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.29); catalogued as rs758146372; called by muse, mutect2, varscan2
- OGFOD1 | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 204/991 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs778510251, COSV55859371; called by muse, mutect2, varscan2
- OR5H15 | c.926-1A>G p.X309_splice | Splice Site (SNP) | VAF 33/148 reads (22%) | catalogued as rs763110852; called by muse, mutect2
- OR8G1 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 213/862 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as rs756646568; called by muse, mutect2, varscan2
- PAPSS2 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 161/710 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755518410, COSV100753414; called by muse, mutect2, varscan2
- PAWR | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 120/490 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.475); catalogued as rs8176806; called by muse, mutect2, varscan2
- PCCB | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 237/1457 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs968929973; called by muse, mutect2, varscan2
- PCM1 | c.3308C>T p.S1103L | Missense Mutation (SNP) | VAF 199/954 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.395); catalogued as rs199506881, COSV61519836; called by muse, mutect2, varscan2
- PDF | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 183/857 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773714805; called by muse, mutect2, varscan2
- PLCG1 | c.2507A>G p.K836R | Missense Mutation (SNP) | VAF 209/1162 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.631); catalogued as rs1231040166; called by muse, mutect2, varscan2
- POLRMT | c.2030C>G p.A677G | Missense Mutation (SNP) | VAF 160/747 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs762201108; called by muse, mutect2, varscan2
- POM121C | c.3524C>T p.S1175L (on ENST00000607367; = p.S933L on NM_001099415.3) | Missense Mutation (SNP) | VAF 247/1255 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs587604076, COSV57547561; called by muse, mutect2, varscan2
- POTEG | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 76/1166 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1432473969; called by muse, mutect2
- PPL | c.4531G>A p.D1511N | Missense Mutation (SNP) | VAF 181/762 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.134); catalogued as rs958895700; called by muse, mutect2, varscan2
- PPP1R12A | c.2166A>T p.Q722H | Missense Mutation (SNP) | VAF 271/1106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs749084000; called by muse, mutect2, varscan2
- PTPRB | c.3116G>A p.R1039H | Missense Mutation (SNP) | VAF 188/820 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs112670000; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 202/801 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs150741859; called by muse, mutect2, varscan2
- RASAL3 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 143/671 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs374340432; called by muse, mutect2, varscan2
- REC8 | c.1181T>C p.I394T | Missense Mutation (SNP) | VAF 200/857 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs201586333; called by muse, mutect2, varscan2
- RFX8 | c.397A>G p.M133V (on ENST00000646446; = p.M62V on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/453 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775822262; called by muse, mutect2, varscan2
- RGPD3 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 113/990 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1292367072; called by muse, mutect2, varscan2
- RGPD4 | c.2726C>A p.S909* | Nonsense Mutation (SNP) | VAF 88/446 reads (20%) | catalogued as rs201500065; called by muse, mutect2, varscan2
- RHBDL1 | c.793G>A p.A265T (on ENST00000219551 / NM_001318733.2; = p.A200T on NM_001278720.2) | Missense Mutation (SNP) | VAF 128/587 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs138524732; called by muse, mutect2, varscan2
- RNF10 | c.1618A>C p.K540Q | Missense Mutation (SNP) | VAF 196/836 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as rs1056432036; called by muse, mutect2, varscan2
- RPL6 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 245/1253 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV52518045; called by muse, mutect2, varscan2
- RPTOR | c.3454A>G p.T1152A | Missense Mutation (SNP) | VAF 136/662 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.437); catalogued as rs1357242716; called by muse, mutect2, varscan2
- SDK1 | c.3239A>G p.N1080S | Missense Mutation (SNP) | VAF 321/1361 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs1363562992; called by muse, mutect2, varscan2
- SEC31A | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 193/888 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs762452791; called by muse, mutect2, varscan2
- SH3BP4 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 242/1047 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs777139132; called by muse, mutect2, varscan2
- SLC15A5 | c.1469A>G p.Y490C | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs969109497; called by muse, mutect2, varscan2
- SLC27A5 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 175/841 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs764918463, COSV99036655; called by muse, mutect2, varscan2
- SLC29A3 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 202/984 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs199861210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC37A4 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 299/1266 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs782308530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A15 | c.1570T>C p.F524L | Missense Mutation (SNP) | VAF 198/838 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs990452453; called by muse, mutect2, varscan2
- SLIT3 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 195/867 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs372601219; called by muse, mutect2, varscan2
- SLPI | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 192/1008 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1261559636; called by muse, mutect2, varscan2
- SPECC1 | c.839C>G p.T280S | Missense Mutation (SNP) | VAF 185/1074 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.349); catalogued as rs757827778; called by muse, mutect2, varscan2
- SPOCK2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 178/779 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs988182177, COSV100436318; called by muse, mutect2, varscan2
- SPTB | c.6450G>T p.E2150D | Missense Mutation (SNP) | VAF 193/1038 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs548137633, COSV61552759; called by muse, mutect2, varscan2
- STAR | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 108/480 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.447); catalogued as rs564329147, COSV52418641; called by muse, mutect2, varscan2
- SUCLG2 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 145/676 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180701292; called by muse, mutect2, varscan2
- TAF1L | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 208/1195 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs138027604; called by muse, mutect2, varscan2
- TCP11X2 | c.733T>C p.W245R | Missense Mutation (SNP) | VAF 382/1718 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1406713763; called by muse, mutect2, varscan2
- TIMP4 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 209/1026 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751613583; called by muse, mutect2, varscan2
- TMPRSS15 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 257/1252 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs369769966; called by muse, mutect2, varscan2
- TMPRSS7 | c.1274G>T p.G425V (on ENST00000452346; = p.G299V on NM_001042575.2) | Missense Mutation (SNP) | VAF 167/685 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs373464287; called by muse, mutect2, varscan2
- TNFRSF21 | c.292A>T p.R98W | Missense Mutation (SNP) | VAF 139/627 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs746388779; called by muse, mutect2, varscan2
- TRIL | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 302/1545 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs538009689; called by muse, mutect2, varscan2
- TRIM66 | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 153/741 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs981082166; called by muse, mutect2, varscan2
- TRMT9B | c.868T>A p.S290T | Missense Mutation (SNP) | VAF 254/1043 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.039); catalogued as rs370876933; called by muse, mutect2
- TXNDC5 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 212/992 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs146368083; called by muse, mutect2, varscan2
- UBXN10 | c.27A>G p.I9M | Missense Mutation (SNP) | VAF 167/771 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs369575965; called by muse, mutect2, varscan2
- USH2A | c.7787A>G p.Y2596C | Missense Mutation (SNP) | VAF 155/747 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371685066; called by muse, mutect2, varscan2
- ZBTB24 | c.943A>G p.S315G | Missense Mutation (SNP) | VAF 181/748 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs759942793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF223 | c.1431_1433del p.L477del | In Frame Del (DEL) | VAF 98/408 reads (24%) | catalogued as rs755714801; called by pindel, varscan2
- ZNF251 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 199/871 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs375520552; called by muse, mutect2, varscan2
- ZNF275 | c.744T>G p.D248E | Missense Mutation (SNP) | VAF 172/882 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs782180578; called by muse, mutect2, varscan2
- ZNF808 | c.597G>T p.R199S | Missense Mutation (SNP) | VAF 263/1226 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.036); catalogued as rs769221742, COSV63120519; called by muse, mutect2, varscan2
- ZNF808 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 162/652 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs141948878; called by muse, mutect2, varscan2
- ZSWIM1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 234/1307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140182403; called by muse, mutect2, varscan2
- ACTR5 | c.274T>C p.W92R | Missense Mutation (SNP) | VAF 153/999 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.5654C>T p.T1885I | Missense Mutation (SNP) | VAF 291/1401 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- C17orf75 | c.1182_1183dup p.S395Kfs*8 | Frame Shift Ins (INS) | VAF 130/571 reads (23%) | called by mutect2, pindel, varscan2
- COPG1 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 139/768 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CYFIP1 | c.3277T>C p.F1093L | Missense Mutation (SNP) | VAF 144/700 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- INTS3 | c.658C>G p.H220D | Missense Mutation (SNP) | VAF 238/1100 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIAA1958 | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 166/768 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHX4 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 241/1376 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- MYOF | c.4622A>G p.Q1541R | Missense Mutation (SNP) | VAF 309/1024 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- NSD2 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 161/728 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8I2 | c.497_524delinsGGCGTTCTGTGATTCCGGCATCAATC p.L166Wfs*13 | Frame Shift Del (DEL) | VAF 158/1401 reads (11%) | called by muse*, pindel, varscan2*
- SETD5 | c.3177C>G p.N1059K | Missense Mutation (SNP) | VAF 142/662 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SHOC1 | c.3604C>A p.Q1202K | Missense Mutation (SNP) | VAF 154/764 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SYMPK | c.2135A>G p.Q712R | Missense Mutation (SNP) | VAF 158/594 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TEK | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 252/1005 reads (25%) | called by muse, mutect2, varscan2
- TET3 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 128/689 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM49C | c.5del p.N2Ifs*18 | Frame Shift Del (DEL) | VAF 63/498 reads (13%) | called by mutect2, pindel, varscan2
- TUBB8 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 203/1176 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.499); called by muse, varscan2
- ADRM1 | c.435C>T p.H145= | Silent (SNP) | VAF 188/1084 reads (17%) | catalogued as rs190468988; called by muse, mutect2
- AGGF1 | c.747T>A p.R249= | Silent (SNP) | VAF 191/671 reads (28%) | catalogued as rs772703024, COSV104397803, COSV57230223; called by muse, mutect2, varscan2
- ANKRD11 | c.4860C>G p.L1620= | Silent (SNP) | VAF 177/802 reads (22%) | catalogued as rs541087910; called by muse, mutect2, varscan2
- AOC3 | c.2070C>T p.D690= | Silent (SNP) | VAF 146/898 reads (16%) | catalogued as rs537727054; called by muse, mutect2, varscan2
- ARHGAP32 | c.4437C>T p.P1479= (on ENST00000310343 / NM_001378025.1; = p.P1130= on NM_014715.4) | Silent (SNP) | VAF 192/908 reads (21%) | catalogued as rs114575545; called by muse, mutect2, varscan2
- ARHGEF38 | c.2142C>T p.D714= | Silent (SNP) | VAF 131/453 reads (29%) | catalogued as rs201949917, COSV70365269; called by muse, mutect2, varscan2
- ARMCX2 | c.33G>A p.A11= | Silent (SNP) | VAF 303/1284 reads (24%) | catalogued as rs782784093; called by muse, mutect2, varscan2
- BCL11B | c.1239C>T p.P413= (on ENST00000357195 / NM_001282237.2; = p.P342= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 187/943 reads (20%) | catalogued as rs931484413; called by muse, mutect2, varscan2
- BDP1 | c.3639C>T p.G1213= | Silent (SNP) | VAF 160/771 reads (21%) | catalogued as rs764433594; called by muse, varscan2
- C12orf56 | c.1161G>A p.L387= (on ENST00000543942 / NM_001170633.2; = p.L227= on NM_001099676.3) | Silent (SNP) | VAF 147/698 reads (21%) | catalogued as rs763177068; called by muse, mutect2, varscan2
- CARNMT1 | c.153G>A p.T51= | Silent (SNP) | VAF 208/1013 reads (21%) | catalogued as rs769149721; called by muse, mutect2, varscan2
- CC2D1A | c.2829G>A p.E943= | Silent (SNP) | VAF 128/711 reads (18%) | catalogued as rs1039330361; called by muse, varscan2
- CCDC71L | c.54G>A p.T18= | Silent (SNP) | VAF 220/1096 reads (20%) | catalogued as rs1295084578; called by muse, mutect2, varscan2
- CDCA2 | c.1293C>T p.S431= | Silent (SNP) | VAF 152/685 reads (22%) | catalogued as rs755567957; called by muse, mutect2, varscan2
- CDH11 | c.1263C>T p.I421= | Silent (SNP) | VAF 130/547 reads (24%) | catalogued as rs781549065, COSV51757944; called by muse, mutect2, varscan2
- CDK5RAP3 | c.648T>C p.C216= | Silent (SNP) | VAF 271/1497 reads (18%) | catalogued as rs374055919; called by muse, mutect2, varscan2
- CGN | c.2901C>T p.L967= | Silent (SNP) | VAF 274/1362 reads (20%) | catalogued as rs141191053; called by muse, mutect2, varscan2
- CHAF1A | c.2751G>A p.V917= | Silent (SNP) | VAF 143/577 reads (25%) | catalogued as rs1388370888; called by muse, mutect2, varscan2
- CLCN3 | c.1632G>A p.A544= | Silent (SNP) | VAF 163/676 reads (24%) | catalogued as rs140275154; called by muse, mutect2, varscan2
- CMYA5 | c.5718C>T p.H1906= | Silent (SNP) | VAF 252/1010 reads (25%) | catalogued as rs769471069, COSV101484113; called by muse, mutect2, varscan2
- CNOT1 | c.6006T>C p.N2002= | Silent (SNP) | VAF 233/1016 reads (23%) | catalogued as rs762250421; called by muse, mutect2, varscan2
- CNTN4 | c.2859A>G p.T953= | Silent (SNP) | VAF 202/911 reads (22%) | catalogued as rs750041748; called by muse, mutect2, varscan2
- CNTRL | c.6618C>T p.N2206= | Silent (SNP) | VAF 218/894 reads (24%) | catalogued as rs147458613; called by muse, varscan2
- DHRS13 | c.822C>T p.I274= | Silent (SNP) | VAF 145/835 reads (17%) | catalogued as rs146651013; called by muse, mutect2, varscan2
- EHBP1 | c.462A>G p.L154= | Silent (SNP) | VAF 177/729 reads (24%) | catalogued as rs764223737, COSV50437611; called by muse, mutect2, varscan2
- ELF3 | c.909C>T p.F303= | Silent (SNP) | VAF 224/950 reads (24%) | catalogued as rs202089261, COSV62837952; called by muse, mutect2, varscan2
- EPHB1 | c.1209C>T p.T403= | Silent (SNP) | VAF 142/943 reads (15%) | catalogued as rs375518376, COSV101214840, COSV67656766, COSV67667134; called by muse, mutect2, varscan2
- ERVV-1 | c.831C>A p.T277= | Silent (SNP) | VAF 180/1320 reads (14%) | catalogued as rs756141550; called by muse, mutect2, varscan2
- FAIM | c.189G>A p.A63= | Silent (SNP) | VAF 187/831 reads (23%) | catalogued as rs372907141; called by muse, mutect2, varscan2
- FAM171A2 | c.823C>A p.R275= | Silent (SNP) | VAF 206/1151 reads (18%) | called by muse, mutect2, varscan2
- FAM83H | c.438C>G p.S146= | Silent (SNP) | VAF 211/874 reads (24%) | called by muse, mutect2, varscan2
- FOXJ2 | c.708C>T p.N236= | Silent (SNP) | VAF 177/866 reads (20%) | catalogued as rs772566836; called by muse, mutect2, varscan2
- FYCO1 | c.3831C>T p.D1277= | Silent (SNP) | VAF 244/1170 reads (21%) | catalogued as rs755502918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNAS | c.774C>G p.V258= | Silent (SNP) | VAF 113/564 reads (20%) | catalogued as rs762737117; called by muse, mutect2, varscan2
- GPRASP2 | c.2217G>T p.L739= | Silent (SNP) | VAF 210/768 reads (27%) | catalogued as rs1363511769; called by muse, mutect2, varscan2
- H2AZ2 | c.252G>A p.P84= | Silent (SNP) | VAF 222/905 reads (25%) | catalogued as rs765870002, COSV56062224; called by muse, mutect2, varscan2
- IER5L | c.321C>A p.A107= | Silent (SNP) | VAF 131/622 reads (21%) | catalogued as rs1048104672; called by muse, mutect2, varscan2
- IL7R | c.1071T>C p.T357= | Silent (SNP) | VAF 123/505 reads (24%) | catalogued as rs142726694; ClinVar: likely benign; called by muse, varscan2
- JMJD7-PLA2G4B | c.603C>T p.S201= | Silent (SNP) | VAF 219/917 reads (24%) | catalogued as rs373661420; called by muse, mutect2, varscan2
- KCNJ14 | c.18C>T p.A6= | Silent (SNP) | VAF 95/512 reads (19%) | catalogued as rs746464992; called by muse, mutect2, varscan2
- KDM4B | c.957C>T p.D319= | Silent (SNP) | VAF 143/640 reads (22%) | catalogued as rs776309320; called by muse, mutect2, varscan2
- KMT2C | c.264A>G p.Q88= | Silent (SNP) | VAF 167/699 reads (24%) | catalogued as rs769002436; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT31 | c.1086C>T p.S362= | Silent (SNP) | VAF 263/1527 reads (17%) | catalogued as rs774179895, COSV52437191; called by muse, mutect2, varscan2
- LAMP3 | c.981G>A p.V327= | Silent (SNP) | VAF 185/816 reads (23%) | catalogued as rs755359259, COSV55613830; called by muse, mutect2, varscan2
- LAMP3 | c.921A>C p.G307= | Silent (SNP) | VAF 68/370 reads (18%) | catalogued as rs757480815; called by muse, varscan2
- LRPAP1 | c.33C>T p.R11= | Silent (SNP) | VAF 169/912 reads (19%) | catalogued as rs200330132; called by muse, mutect2, varscan2
- LVRN | c.1302C>A p.I434= | Silent (SNP) | VAF 197/746 reads (26%) | catalogued as rs369931696; called by muse, mutect2, varscan2
- MAGEC1 | c.792C>G p.A264= | Silent (SNP) | VAF 362/642 reads (56%) | catalogued as rs144495362, COSV53571327; called by muse, mutect2
- MAGEC3 | c.1692C>G p.P564= | Silent (SNP) | VAF 213/786 reads (27%) | catalogued as rs183587376; called by muse, mutect2, varscan2
- MAGI1 | c.660G>A p.K220= | Silent (SNP) | VAF 286/1265 reads (23%) | called by muse, mutect2, varscan2
- MAP3K5 | c.18C>T p.D6= | Silent (SNP) | VAF 150/789 reads (19%) | catalogued as rs375548547; called by muse, mutect2, varscan2
- MEGF8 | c.2961C>T p.H987= (on ENST00000251268 / NM_001271938.2; = p.H920= on NM_001410.3) | Silent (SNP) | VAF 178/853 reads (21%) | catalogued as rs760802467, COSV52082576; ClinVar: likely benign; called by muse, mutect2, varscan2
- MTO1 | c.1044G>T p.G348= | Silent (SNP) | VAF 226/846 reads (27%) | catalogued as rs770890953; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYPN | c.2709C>T p.Y903= | Silent (SNP) | VAF 110/500 reads (22%) | catalogued as rs772657844; ClinVar: likely benign; called by muse, mutect2, varscan2
- NACC2 | c.1074C>T p.R358= | Silent (SNP) | VAF 163/674 reads (24%) | catalogued as rs769548655; called by muse, mutect2, varscan2
- NCOR2 | c.7335C>T p.R2445= | Silent (SNP) | VAF 204/1218 reads (17%) | catalogued as rs766761610; called by muse, mutect2, varscan2
- NET1 | c.108C>T p.S36= | Silent (SNP) | VAF 76/277 reads (27%) | catalogued as rs747310426; called by muse, mutect2, varscan2
- NOTCH2NLA | c.285A>G p.Q95= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs1132928; called by mutect2, varscan2
- NPC1 | c.3159C>T p.D1053= | Silent (SNP) | VAF 259/1156 reads (22%) | catalogued as rs201460899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OSBPL10 | c.1668T>C p.H556= | Silent (SNP) | VAF 188/893 reads (21%) | catalogued as rs768751290; called by muse, mutect2, varscan2
- OSBPL11 | c.1977G>A p.T659= | Silent (SNP) | VAF 194/880 reads (22%) | catalogued as rs753171031, COSV56174488; called by muse, varscan2
- PAPLN | c.1341C>T p.S447= (on ENST00000554301; = p.S420= on NM_173462.4) | Silent (SNP) | VAF 216/1126 reads (19%) | catalogued as rs147158613; called by muse, mutect2, varscan2
- PAWR | c.228C>A p.G76= | Silent (SNP) | VAF 99/646 reads (15%) | catalogued as rs373998397; called by muse, mutect2, varscan2
- PCLO | c.2853A>G p.Q951= | Silent (SNP) | VAF 200/874 reads (23%) | catalogued as rs372528862; called by muse, mutect2, varscan2
- PEX5L | c.441C>A p.I147= | Silent (SNP) | VAF 318/1276 reads (25%) | catalogued as rs944492711; called by muse, mutect2, varscan2
- PIEZO1 | c.4788G>A p.A1596= | Silent (SNP) | VAF 229/1069 reads (21%) | catalogued as rs779767428; called by muse, mutect2, varscan2
- PIGZ | c.825G>A p.T275= | Silent (SNP) | VAF 261/1316 reads (20%) | catalogued as rs1261349332, COSV53013908; called by muse, mutect2, varscan2
- PLXNB2 | c.3885C>T p.D1295= | Silent (SNP) | VAF 267/885 reads (30%) | catalogued as rs373203381; called by muse, mutect2, varscan2
- PLXNB3 | c.600G>A p.V200= | Silent (SNP) | VAF 136/624 reads (22%) | catalogued as rs782463561; called by muse, mutect2, varscan2
- POLG | c.2820C>T p.G940= | Silent (SNP) | VAF 206/992 reads (21%) | catalogued as rs571319491; called by muse, mutect2, varscan2
- POLL | c.663C>T p.T221= | Silent (SNP) | VAF 186/985 reads (19%) | catalogued as rs761546004, COSV54576618; called by muse, mutect2
- POLR3A | c.1605G>A p.G535= | Silent (SNP) | VAF 235/969 reads (24%) | catalogued as rs988649580; called by muse, varscan2
- PTPN7 | c.240C>T p.H80= (on ENST00000495688; = p.H119= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 197/880 reads (22%) | catalogued as rs765458530; called by muse, mutect2, varscan2
- RRNAD1 | c.909T>C p.A303= | Silent (SNP) | VAF 146/639 reads (23%) | catalogued as rs1465496659; called by muse, mutect2, varscan2
- SCRT2 | c.906C>T p.P302= | Silent (SNP) | VAF 133/746 reads (18%) | catalogued as rs908610113; called by muse, mutect2, varscan2
- SETD1B | c.3672A>C p.A1224= | Silent (SNP) | VAF 171/948 reads (18%) | catalogued as rs1343315500; called by muse, mutect2, varscan2
- SETD2 | c.2040A>G p.E680= | Silent (SNP) | VAF 126/756 reads (17%) | catalogued as rs374447180; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLAIN1 | c.438C>T p.G146= (on ENST00000466548; = p.G168= on NM_001242868.2) | Silent (SNP) | VAF 154/715 reads (22%) | catalogued as rs1052930435; called by muse, mutect2, varscan2
- SLC5A11 | c.1785C>T p.F595= | Silent (SNP) | VAF 273/1014 reads (27%) | catalogued as rs376857207; called by muse, mutect2, varscan2
- SLC6A1 | c.1092G>A p.A364= | Silent (SNP) | VAF 107/543 reads (20%) | catalogued as rs199998696, COSV55115251; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLX4 | c.3669G>A p.P1223= | Silent (SNP) | VAF 170/701 reads (24%) | catalogued as rs200407926, COSV53562089; called by muse, mutect2, varscan2
- SPATA31A3 | c.3774C>T p.H1258= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs201679456; called by mutect2, varscan2
- SPDYE2B | c.183C>G p.P61= | Silent (SNP) | VAF 24/208 reads (12%) | catalogued as rs770110106, COSV61016084; called by mutect2, varscan2
- SPRYD4 | c.162T>C p.Y54= | Silent (SNP) | VAF 287/1291 reads (22%) | catalogued as rs780924158; called by muse, mutect2, varscan2
- STAC2 | c.615C>T p.Y205= | Silent (SNP) | VAF 190/1041 reads (18%) | catalogued as rs201624343, COSV61066314; called by muse, mutect2, varscan2
- STAG1 | c.2844T>C p.H948= | Silent (SNP) | VAF 150/671 reads (22%) | catalogued as rs935252575; called by muse, mutect2, varscan2
- TAGLN | c.468G>A p.A156= | Silent (SNP) | VAF 182/805 reads (23%) | catalogued as rs377339313; called by muse, mutect2, varscan2
- TNXB | c.2076C>T p.C692= | Silent (SNP) | VAF 148/592 reads (25%) | catalogued as rs1340605654, COSV64480252; called by muse, mutect2, varscan2
- TOGARAM2 | c.1387T>C p.L463= | Silent (SNP) | VAF 221/925 reads (24%) | catalogued as rs562726147; called by muse, mutect2, varscan2
- TSPAN18 | c.9C>T p.G3= | Silent (SNP) | VAF 143/585 reads (24%) | catalogued as rs768509865, COSV100418549; called by muse, mutect2, varscan2
- TSPEAR | c.1899C>T p.P633= | Silent (SNP) | VAF 202/1526 reads (13%) | catalogued as rs782519406; called by muse, mutect2, varscan2
- TSSK6 | c.444C>T p.R148= | Silent (SNP) | VAF 163/835 reads (20%) | catalogued as rs775064655; called by muse, mutect2, varscan2
- TTC7A | c.1242T>C p.F414= | Silent (SNP) | VAF 180/745 reads (24%) | called by muse, mutect2, varscan2
- TTLL11 | c.2271G>A p.P757= | Silent (SNP) | VAF 130/520 reads (25%) | catalogued as rs545750235, COSV100388754, COSV58647659; called by muse, mutect2, varscan2
- UNC13B | c.3207G>A p.V1069= | Silent (SNP) | VAF 144/579 reads (25%) | catalogued as rs1013992595; called by muse, mutect2, varscan2
- USP22 | c.756G>A p.A252= | Silent (SNP) | VAF 226/1350 reads (17%) | catalogued as rs375910145; called by muse, mutect2, varscan2
- VPS25 | c.466C>T p.L156= | Silent (SNP) | VAF 200/908 reads (22%) | catalogued as rs551753318; called by muse, mutect2, varscan2
- XKR7 | c.552C>T p.L184= | Silent (SNP) | VAF 192/1163 reads (17%) | catalogued as rs759567901; called by muse, mutect2, varscan2
- ZNF160 | c.2328A>G p.L776= | Silent (SNP) | VAF 278/1054 reads (26%) | catalogued as rs778959822; called by muse, mutect2, varscan2
- ZNF180 | c.702C>T p.N234= | Silent (SNP) | VAF 111/492 reads (23%) | catalogued as COSV55424115; called by muse, mutect2, varscan2
- AAK1 | c.2680+92C>T | Intron (SNP) | VAF 92/315 reads (29%) | catalogued as rs942970734; called by muse, mutect2, varscan2
- AC027559.1 | n.333T>C | RNA (SNP) | VAF 130/1118 reads (12%) | catalogued as rs62027634; called by muse, varscan2
- AC073648.1 | n.311T>G | RNA (SNP) | VAF 194/906 reads (21%) | called by muse, mutect2, varscan2
- ADRB2 | c.*32_*33insA | 3'UTR (INS) | VAF 123/392 reads (31%) | catalogued as rs368387516, COSV60005114; called by pindel, varscan2
- AL121820.1 | chr14:68683044 C>G | 3'Flank (SNP) | VAF 100/501 reads (20%) | catalogued as rs374655734; called by muse, mutect2, varscan2
- ALG1 | c.*939C>T | 3'UTR (SNP) | VAF 24/87 reads (28%) | catalogued as rs997651522; called by muse, mutect2, varscan2
- ANXA11 | c.744+99G>A | Intron (SNP) | VAF 52/259 reads (20%) | catalogued as rs991893656; called by muse, mutect2, varscan2
- ARHGAP44 | c.*61G>A | 3'UTR (SNP) | VAF 152/645 reads (24%) | catalogued as rs559002533; called by muse, mutect2, varscan2
- ARHGDIA | c.191-51C>T | Intron (SNP) | VAF 114/572 reads (20%) | catalogued as rs368364854; called by muse, mutect2, varscan2
- ASIC4 | chr2:219514404 ins CTCG | 5'Flank (INS) | VAF 198/1021 reads (19%) | catalogued as rs752410085; called by mutect2, varscan2
- ATP11B | c.3452+86A>G | Intron (SNP) | VAF 60/201 reads (30%) | catalogued as rs752188714; called by muse, mutect2, varscan2
- BAZ2A | c.4077+52C>T | Intron (SNP) | VAF 100/406 reads (25%) | catalogued as rs1015166405; called by muse, mutect2, varscan2
- BLNK | c.1095+50A>G | Intron (SNP) | VAF 87/313 reads (28%) | catalogued as rs781874213; called by muse, mutect2, varscan2
- C19orf57 | c.1764-77C>T | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as rs143109271; called by muse, varscan2
- C2CD6 | c.1581+2543A>G | Intron (SNP) | VAF 186/924 reads (20%) | catalogued as rs949918821; called by muse, mutect2, varscan2
- C5orf60 | n.285G>A | RNA (SNP) | VAF 38/259 reads (15%) | catalogued as rs2411400; called by muse, mutect2, varscan2
- CCDC59 | c.155-10C>G | Intron (SNP) | VAF 140/674 reads (21%) | catalogued as rs936505463; called by mutect2, varscan2
- CCDC93 | c.*62A>G | 3'UTR (SNP) | VAF 93/314 reads (30%) | catalogued as rs551845085; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5042-54T>G | Intron (SNP) | VAF 54/191 reads (28%) | catalogued as rs533936696; called by muse, mutect2, varscan2
- CHORDC1 | c.563+31T>C | Intron (SNP) | VAF 56/236 reads (24%) | catalogued as rs757314095; called by muse, mutect2, varscan2
- CHTF18 | c.1105-11C>G | Intron (SNP) | VAF 54/201 reads (27%) | catalogued as rs200335353; called by muse, mutect2, varscan2
- CNOT3 | c.-18G>A | 5'UTR (SNP) | VAF 122/534 reads (23%) | catalogued as rs377359775; called by muse, mutect2, varscan2
- CNOT7 | c.312-90T>C | Intron (SNP) | VAF 37/101 reads (37%) | catalogued as rs1032403831; called by muse, mutect2, varscan2
- DDB2 | c.456+64C>T | Intron (SNP) | VAF 124/494 reads (25%) | catalogued as rs529323758; called by muse, mutect2, varscan2
- DNAAF5 | c.1931+1261G>A | Intron (SNP) | VAF 34/148 reads (23%) | catalogued as rs769355495; called by muse, mutect2, varscan2
- DNAH9 | c.5814+44A>G | Intron (SNP) | VAF 75/321 reads (23%) | catalogued as rs372327832; called by muse, mutect2, varscan2
- DNASE1L3 | c.801+56G>T | Intron (SNP) | VAF 113/500 reads (23%) | catalogued as rs755107366; called by muse, mutect2, varscan2
- DPAGT1 | c.161+22C>T | Intron (SNP) | VAF 199/873 reads (23%) | catalogued as rs747953775, COSV62614704; called by muse, mutect2, varscan2
- ECE2 | c.1973-41A>T | Intron (SNP) | VAF 159/634 reads (25%) | catalogued as rs981536997; called by muse, mutect2, varscan2
- EIF3E | c.1299+74A>T | Intron (SNP) | VAF 64/213 reads (30%) | called by muse, mutect2, varscan2
- EXOSC7 | c.-28C>T | 5'UTR (SNP) | VAF 123/518 reads (24%) | catalogued as rs1004786756; called by muse, mutect2, varscan2
- FARP1 | c.3056+61A>T | Intron (SNP) | VAF 59/313 reads (19%) | catalogued as rs1048822741; called by muse, mutect2, varscan2
- GCC1 | c.-71C>G | 5'UTR (SNP) | VAF 25/85 reads (29%) | catalogued as rs1346909635; called by muse, mutect2, varscan2
- GJA5 | chr1:147777692 A>G | 5'Flank (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- GRK6 | c.1677+208C>T | Intron (SNP) | VAF 154/639 reads (24%) | catalogued as rs775853411; called by muse, mutect2, varscan2
- HAGHL | c.*229C>T | 3'UTR (SNP) | VAF 176/818 reads (22%) | catalogued as rs1555489402, COSV52401331; called by muse, mutect2, varscan2
- HBG2 | c.*77A>G | 3'UTR (SNP) | VAF 82/380 reads (22%) | catalogued as rs769706828; called by muse, mutect2, varscan2
- IFNG | c.-25C>A | 5'UTR (SNP) | VAF 134/380 reads (35%) | catalogued as rs374846391, COSV57491301; called by muse, mutect2, varscan2
- ITGA3 | c.334+52G>C | Intron (SNP) | VAF 78/335 reads (23%) | catalogued as rs949683652, COSV99144499; called by muse, mutect2, varscan2
- KAT14 | chr20:18137935 G>A | 5'Flank (SNP) | VAF 82/371 reads (22%) | catalogued as rs748839467; called by muse, mutect2, varscan2
- KEL | c.1315-39C>T | Intron (SNP) | VAF 94/313 reads (30%) | catalogued as rs751989887; called by muse, mutect2, varscan2
- KMT2E | c.1130+22T>C | Intron (SNP) | VAF 70/267 reads (26%) | catalogued as rs745896642; called by muse, mutect2, varscan2
- LEKR1 | c.*1066G>A | 3'UTR (SNP) | VAF 189/925 reads (20%) | catalogued as rs375807110; called by muse, mutect2, varscan2
- MAP3K9 | c.2027-424G>A | Intron (SNP) | VAF 156/790 reads (20%) | catalogued as rs773762945, COSV67119711; called by muse, mutect2, varscan2
- METTL21A | c.-29-35G>T | Intron (SNP) | VAF 63/269 reads (23%) | called by muse, mutect2, varscan2
- METTL25 | c.259+67C>A | Intron (SNP) | VAF 86/328 reads (26%) | called by muse, mutect2, varscan2
- MPI | c.670+77G>T | Intron (SNP) | VAF 71/244 reads (29%) | called by muse, mutect2, varscan2
- MPO | c.-64A>G | 5'UTR (SNP) | VAF 96/401 reads (24%) | catalogued as rs1281819571; called by muse, mutect2, varscan2
- MPRIP | c.*133T>C | 3'UTR (SNP) | VAF 120/565 reads (21%) | catalogued as rs909936135; called by muse, mutect2, varscan2
- MRPL43 | c.529-2105A>G | Intron (SNP) | VAF 144/632 reads (23%) | catalogued as rs377674341; called by muse, mutect2, varscan2
- MSH2 | c.*76C>T | 3'UTR (SNP) | VAF 62/245 reads (25%) | catalogued as rs368904632; called by muse, mutect2, varscan2
- MST1 | c.-32A>G | 5'UTR (SNP) | VAF 36/236 reads (15%) | catalogued as rs762771116; called by muse, mutect2, varscan2
- MTTP | c.-79C>T | 5'UTR (SNP) | VAF 54/200 reads (27%) | catalogued as rs145929301; called by muse, mutect2, varscan2
- MUC2 | chr11:1095547 G>A | 3'Flank (SNP) | VAF 210/1278 reads (16%) | catalogued as rs1189652247; called by muse, mutect2, varscan2
- NDUFS6 | c.*63C>T | 3'UTR (SNP) | VAF 109/466 reads (23%) | catalogued as rs146485974; called by muse, mutect2, varscan2
- NDUFV2 | c.54+95G>A | Intron (SNP) | VAF 38/287 reads (13%) | catalogued as rs764267758; called by muse, mutect2, varscan2
- NELFE | c.942+29A>G | Intron (SNP) | VAF 140/516 reads (27%) | catalogued as rs760791250; called by muse, mutect2, varscan2
- NRG3 | chr10:82985675 A>T | 3'Flank (SNP) | VAF 64/182 reads (35%) | catalogued as rs903526652, COSV100931524; called by muse, mutect2, varscan2
- NUS1 | c.-25G>A | 5'UTR (SNP) | VAF 96/366 reads (26%) | catalogued as rs759580772; called by muse, mutect2, varscan2
- NUTM2B | c.*89C>T | 3'UTR (SNP) | VAF 10/50 reads (20%) | catalogued as rs1467382954, COSV61136494; called by mutect2, varscan2
- PDLIM1P2 | chr17:21440190 G>T | 3'Flank (SNP) | VAF 12/74 reads (16%) | catalogued as rs868951217; called by muse, mutect2
- PHACTR1 | c.1727+26C>A | Intron (SNP) | VAF 82/286 reads (29%) | catalogued as COSV60683862; called by muse, mutect2
- PHF20L1 | c.1183+82T>C | Intron (SNP) | VAF 80/334 reads (24%) | catalogued as rs1050902946; called by mutect2, varscan2
- PLCH2 | c.2959+137C>T | Intron (SNP) | VAF 110/582 reads (19%) | catalogued as rs190731502; called by muse, varscan2
- PLPP5 | c.*15C>T | 3'UTR (SNP) | VAF 110/513 reads (21%) | catalogued as rs374989257; called by muse, mutect2, varscan2
- PLXNA4 | c.5056-32G>A | Intron (SNP) | VAF 116/549 reads (21%) | catalogued as rs779869685; called by muse, mutect2, varscan2
- PSMD6 | c.145+43C>T | Intron (SNP) | VAF 160/820 reads (20%) | catalogued as rs1188667043; called by muse, mutect2, varscan2
- RASGEF1B | c.438+24G>A | Intron (SNP) | VAF 131/574 reads (23%) | catalogued as rs946643210; called by muse, mutect2, varscan2
- RBBP4 | c.*67A>G | 3'UTR (SNP) | VAF 53/178 reads (30%) | called by muse, mutect2, varscan2
- RGS6 | c.792+89C>G | Intron (SNP) | VAF 90/334 reads (27%) | catalogued as rs767093028; called by muse, mutect2, varscan2
- RN7SKP78 | chr10:6144966 G>A | 5'Flank (SNP) | VAF 139/593 reads (23%) | catalogued as rs1472347761; called by muse, mutect2, varscan2
- RNU1-143P | chr1:143795900 T>C | 5'Flank (SNP) | VAF 39/234 reads (17%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81109299 T>C | 5'Flank (SNP) | VAF 248/893 reads (28%) | catalogued as rs367672310; called by muse, mutect2, varscan2
- RPS24 | c.390+582_390+585del | Intron (DEL) | VAF 40/146 reads (27%) | catalogued as rs989240364; called by mutect2, varscan2
- RPS25 | c.100-19G>A | Intron (SNP) | VAF 87/365 reads (24%) | called by muse, mutect2, varscan2
- RPS27 | c.*8_*9del | 3'UTR (DEL) | VAF 174/986 reads (18%) | catalogued as rs1413421715; called by pindel, varscan2
- RUFY2 | c.1310+25C>A | Intron (SNP) | VAF 139/585 reads (24%) | catalogued as rs752904525, COSV56259128; called by muse, mutect2, varscan2
- SLC35B1 | chr17:49707981 C>A | 5'Flank (SNP) | VAF 53/232 reads (23%) | catalogued as rs563923371; called by muse, mutect2, varscan2
- SP110 | c.1591-18C>T | Intron (SNP) | VAF 67/220 reads (30%) | catalogued as rs199943105; called by muse, mutect2, varscan2
- SPACA6 | c.215-44G>A | Intron (SNP) | VAF 31/142 reads (22%) | catalogued as rs544288417; called by muse, mutect2, varscan2
- SPATA31C1 | n.1428G>A | RNA (SNP) | VAF 209/872 reads (24%) | catalogued as rs758242014; called by muse, mutect2, varscan2
- SREK1 | chr5:66144283 C>T | 5'Flank (SNP) | VAF 73/328 reads (22%) | catalogued as rs1009128839; called by muse, mutect2, varscan2
- SUV39H2 | c.-5A>G | 5'UTR (SNP) | VAF 135/580 reads (23%) | catalogued as rs375333545; called by muse, mutect2, varscan2
- SVIL | c.6558+48_6558+50delinsAC | Intron (DEL) | VAF 134/812 reads (17%) | catalogued as rs1554799371; called by pindel, varscan2*
- TM4SF1 | c.-69C>T | 5'UTR (SNP) | VAF 36/157 reads (23%) | catalogued as rs889544032; called by muse, varscan2
- TMA7 | c.-7A>G | 5'UTR (SNP) | VAF 232/1216 reads (19%) | catalogued as rs767698039; called by muse, mutect2, varscan2
- TTN | c.10360+4523A>C | Intron (SNP) | VAF 246/1151 reads (21%) | catalogued as rs200760091; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TUT1 | c.1475-84C>T | Intron (SNP) | VAF 73/243 reads (30%) | catalogued as rs1433352750; called by muse, mutect2, varscan2
- TYW5 | c.303+79T>C | Intron (SNP) | VAF 73/232 reads (31%) | catalogued as rs749384306; called by muse, mutect2, varscan2
- UCN3 | c.*56G>C | 3'UTR (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2
- WDR82 | c.-85C>T | 5'UTR (SNP) | VAF 37/214 reads (17%) | catalogued as rs1209798791; called by muse, mutect2, varscan2
- YEATS2 | c.4087-64A>C | Intron (SNP) | VAF 48/187 reads (26%) | catalogued as rs367694796; called by muse, mutect2, varscan2
- ZC3H18 | c.2109-92G>A | Intron (SNP) | VAF 55/170 reads (32%) | catalogued as rs951116376; called by muse, mutect2, varscan2
- ZGLP1 | c.605-72C>G | Intron (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- ZNF419 | c.33+27C>T | Intron (SNP) | VAF 158/667 reads (24%) | catalogued as rs374962089; called by muse, mutect2, varscan2
- ZNF749 | c.15+32A>C | Intron (SNP) | VAF 110/521 reads (21%) | catalogued as rs371562832; called by muse, mutect2, varscan2
